Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92O, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92O-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Thymoma, type ANDS 8581/1
Date Thymus CB79
JW 4/2/14

Patient Name:

MRN:

DOB:

Gender: M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: Thymectomy

DIAGNOSIS

Thymectomy:

- Type A (WHO Classification)/spindle cell thymoma.
- Tumor 3 cm in greatest diameter, completely encapsulated.
- No invasion into pericapsular adipose tissue.
- Painted resection margin negative for tumor.
- pT1N0M0 (stage I).

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Mediastinal mass

GROSS DESCRIPTION

The specimen container labeled with the patient's name and as "thymectomy", contains a thymus measuring 13.0 cm SI x 12.0 cm ML x 1.0 cm AP, received in 10% buffered formalin. On the lateral side of one lobe, there is a white solid tumor measuring 3.0 x 2.6 x 2.4 cm in maximum dimension. This tumor is well described by a layer of capsule. The total weight of the specimen is 71.9 grams. The surface is painted with silver nitrate.

Sections are submitted as follows:

1A-1H - tumor submitted in toto

1I-1L - representative sections of thymus from the same side of the tumor, from superior to inferior

1M-1P - representative sections of the other lobe, from superior to inferior.

Status: complete

Page: 1 of 2

[page 2 of 2]
Patient Name:

MRN:

DOB:

Gender:M

Ordering

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Source: NCI Genomic Data Commons file 86c08194-ed22-4e64-a8d7-125731fe560c (TCGA-XU-A92O.E560C9EB-822B-495B-B7E2-B02770B357C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).